Somatic mutation profile of tumor specimen TCGA-UB-A7MB-01A (aliquot TCGA-UB-A7MB-01A-11D-A33Q-10) from TCGA case TCGA-UB-A7MB, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 24.5 years (8,951 days).
Specimen TCGA-UB-A7MB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0422c6f2-b53e-42cc-8a17-6151ce5a5c72.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UB-A7MB-10A (Blood Derived Normal), aliquot TCGA-UB-A7MB-10A-01D-A33Q-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/226968c0-c961-4057-8119-0cd67ff5e4cb

The open-access MAF lists 1,629 somatic variants for this specimen: 1,213 protein-altering or splice-affecting, 384 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,058, Silent 384, Nonsense Mutation 65, Splice Site 57, Splice Region 17, Frame Shift Del 12, RNA 11, 3'UTR 8, Intron 8, Nonstop Mutation 3, 5'UTR 3, 5'Flank 2.

Variants (750 of 1,629; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ELANE | c.290A>C p.Q97P | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1085307717, CM135423, CM147613, COSV55049618; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 55/67 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057520007, COSV52665440, COSV52677268, COSV52688506; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.7051C>A p.H2351N (on ENST00000272895 / NM_173076.3; = p.H2033N on NM_015657.3) | Missense Mutation (SNP) | VAF 65/135 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV55975744; called by muse, mutect2, varscan2
- ABCA13 | c.5527G>T p.V1843F | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.765); catalogued as COSV70044662; called by muse, mutect2, varscan2
- ABCA13 | c.11846A>T p.K3949M | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV71288366, COSV71294498; called by muse, mutect2, varscan2
- ABCA13 | c.13239C>A p.N4413K | Missense Mutation (SNP) | VAF 59/158 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV68950743; called by muse, mutect2, varscan2
- ABCA3 | c.1742-2A>G p.X581_splice | Splice Site (SNP) | VAF 27/67 reads (40%) | catalogued as COSV57059992; called by muse, mutect2, varscan2
- ABCA7 | c.303-2A>T p.X101_splice | Splice Site (SNP) | VAF 4/13 reads (31%) | catalogued as COSV54037423; called by muse, mutect2, varscan2
- ABCB5 | c.524G>C p.S175T | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs753883618, COSV51720909; called by mutect2, varscan2
- ABCB5 | c.3005G>T p.S1002I (on ENST00000404938 / NM_001163941.2; = p.S557I on NM_178559.6) | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV51720921; called by muse, mutect2, varscan2
- ABCD2 | c.941T>A p.V314E | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV58055288; called by muse, mutect2, varscan2
- ABHD2 | c.195-2A>G p.X65_splice | Splice Site (SNP) | VAF 29/57 reads (51%) | catalogued as COSV61776155; called by muse, mutect2, varscan2
- AC004922.1 | c.407A>G p.H136R | Missense Mutation (SNP) | VAF 76/148 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as COSV53559361; called by muse, mutect2, varscan2
- AC006059.2 | c.1474A>T p.S492C | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV59609532; called by muse, mutect2, varscan2
- AC024598.1 | c.1281A>C p.Q427H | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.466); catalogued as COSV60824831; called by muse, mutect2, varscan2
- ACAN | c.1120A>G p.T374A | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61369560; called by muse, mutect2, varscan2
- ACSM3 | c.492A>T p.Q164H | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV55504155; called by muse, mutect2, varscan2
- ADAD2 | c.1601T>C p.V534A (on ENST00000315906 / NM_001145400.2; = p.V616A on NM_139174.4) | Missense Mutation (SNP) | VAF 23/24 reads (96%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs1278702392, COSV51894933; called by muse, mutect2, varscan2
- ADAM23 | c.509+2T>C p.X170_splice | Splice Site (SNP) | VAF 105/229 reads (46%) | catalogued as COSV52230359; called by muse, mutect2, varscan2
- ADAM29 | c.811A>C p.K271Q | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0.076); catalogued as COSV63668205; called by muse, mutect2, varscan2
- ADAM29 | c.2374C>A p.P792T | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.097); catalogued as COSV63668221; called by muse, varscan2
- ADAMTS3 | c.247A>G p.N83D | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54402983; called by muse, mutect2, varscan2
- ADAMTS8 | c.1894A>T p.R632W | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV57297814; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4721A>G p.K1574R | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.76); PolyPhen benign (0.046); catalogued as COSV65879218; called by muse, mutect2, varscan2
- ADCY1 | c.735G>T p.Q245H | Missense Mutation (SNP) | VAF 57/115 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.41); catalogued as COSV52042577; called by muse, mutect2, varscan2
- ADCY2 | c.2997G>C p.V999= | Splice Region (SNP) | VAF 38/96 reads (40%) | catalogued as COSV57900777; called by muse, mutect2, varscan2
- ADCY4 | c.2333T>A p.L778* | Nonsense Mutation (SNP) | VAF 38/65 reads (58%) | catalogued as COSV60257662; called by muse, mutect2, varscan2
- ADGRE3 | c.952A>T p.R318W | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV53734908, COSV53735332; called by muse, mutect2, varscan2
- ADGRV1 | c.12005A>G p.N4002S | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757610485, COSV67995528; called by muse, mutect2, varscan2
- ADGRV1 | c.12133G>A p.E4045K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV67977930; called by muse, mutect2, varscan2
- ADRA1D | c.1291T>G p.W431G | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV65242018; called by mutect2, varscan2
- ADRB2 | c.554A>G p.Y185C | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60006280; called by muse, mutect2, varscan2
- AFF2 | c.1310A>T p.E437V | Missense Mutation (SNP) | VAF 40/45 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54007963; called by muse, mutect2, varscan2
- AGAP2 | c.2708A>T p.Q903L (on ENST00000547588 / NM_001122772.2; = p.Q547L on NM_014770.4) | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV57731819; called by muse, mutect2, varscan2
- AGBL1 | c.2216T>A p.L739H | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66872850; called by muse, mutect2, varscan2
- AGFG1 | c.851A>T p.H284L | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV59514789; called by muse, mutect2, varscan2
- AGO1 | c.2182A>G p.I728V | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as COSV64596553; called by muse, mutect2, varscan2
- AHNAK | c.16384A>G p.K5462E | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as COSV57230278; called by muse, mutect2, varscan2
- AHNAK | c.13561A>G p.M4521V | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.8); catalogued as rs753174864, COSV57230302; called by muse, mutect2, varscan2
- AHNAK | c.12155A>G p.H4052R | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs748413979, COSV57230315; called by muse, mutect2, varscan2
- AHNAK2 | c.8096A>T p.Q2699L | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV60930885; called by muse, mutect2, varscan2
- AHNAK2 | c.801A>G p.I267M | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as COSV60930893; called by muse, mutect2, varscan2
- AKAP1 | c.1735G>T p.D579Y | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58473004; called by muse, mutect2, varscan2
- AKAP9 | c.9651-2A>T p.X3217_splice (on ENST00000359028; = p.X3193_splice on NM_005751.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 28/58 reads (48%) | catalogued as COSV62357978; called by muse, mutect2, varscan2
- AKNA | c.3706A>G p.N1236D | Missense Mutation (SNP) | VAF 40/57 reads (70%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as COSV56340277; called by muse, mutect2, varscan2
- ALG10B | c.14A>G p.E5G | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV58144933; called by muse, mutect2, varscan2
- ALPK1 | c.155A>T p.Q52L | Missense Mutation (SNP) | VAF 95/195 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV51592012, COSV99454097; called by muse, mutect2, varscan2
- ALX4 | c.518T>A p.V173E | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.89); PolyPhen benign (0.024); catalogued as COSV61329002; called by muse, mutect2, varscan2
- AMPD1 | c.1691A>T p.Q564L | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as COSV62419028; called by muse, mutect2, varscan2
- AMPH | c.985G>T p.V329F | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV57733691; called by muse, mutect2, varscan2
- ANK2 | c.8887A>G p.T2963A | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.085); catalogued as COSV52188762; called by muse, mutect2, varscan2
- ANKRD11 | c.2672A>G p.D891G | Missense Mutation (SNP) | VAF 35/38 reads (92%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.107); catalogued as COSV56371999; called by muse, mutect2, varscan2
- ANKRD24 | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV53675827; called by muse, mutect2, varscan2
- ANLN | c.149A>T p.Q50L | Missense Mutation (SNP) | VAF 66/133 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as COSV56079544; called by muse, mutect2, varscan2
- ANO9 | c.575T>A p.V192D | Missense Mutation (SNP) | VAF 72/84 reads (86%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV60451862; called by muse, mutect2, varscan2
- AOC3 | c.949T>A p.Y317N | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.192); catalogued as COSV53828837; called by muse, mutect2, varscan2
- AOPEP | c.733A>T p.R245W | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52923840; called by muse, mutect2, varscan2
- AOX1 | c.803A>G p.N268S | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.702); catalogued as COSV65983991; called by muse, mutect2, varscan2
- AP4E1 | c.2477A>G p.Y826C | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.43); catalogued as COSV55920127; called by muse, mutect2, varscan2
- APC2 | c.1518C>G p.H506Q | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.969); catalogued as COSV52018096; called by muse, mutect2, varscan2
- APOB | c.8704A>T p.S2902C | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51952515; called by muse, mutect2, varscan2
- APOD | c.65C>A p.A22E | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV58402790; called by muse, varscan2
- APP | c.1954A>G p.T652A | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.993); catalogued as COSV60999561; called by muse, mutect2, varscan2
- AQP10 | c.112A>T p.T38S | Missense Mutation (SNP) | VAF 36/225 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.412); catalogued as COSV61476081; called by muse, mutect2, varscan2
- ARHGAP22 | c.434G>T p.W145L | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV50987256; called by muse, mutect2, varscan2
- ARHGAP24 | c.1504A>T p.S502C (on ENST00000395184 / NM_001025616.3; = p.S409C on NM_031305.3) | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV51993647; called by muse, mutect2, varscan2
- ARHGAP31 | c.3038T>A p.L1013Q | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV51798996; called by muse, mutect2, varscan2
- ARHGAP33 | c.1817A>T p.K606M | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.046); catalogued as COSV50167653; called by muse, mutect2, varscan2
- ARHGAP35 | c.3337C>T p.Q1113* | Nonsense Mutation (SNP) | VAF 42/95 reads (44%) | catalogued as COSV68335703; called by muse, mutect2, varscan2
- ARHGEF5 | c.4514A>T p.D1505V | Missense Mutation (SNP) | VAF 65/253 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99283227; called by muse, mutect2, varscan2
- ARID1B | c.6310A>T p.R2104W | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51681120; called by muse, mutect2, varscan2
- ARID5B | c.715A>G p.S239G | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.132); catalogued as COSV54429894; called by muse, mutect2, varscan2
- ARL13B | c.445C>G p.L149V (on ENST00000394222 / NM_001174150.2; = p.L42V on NM_144996.4) | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs1258841876, COSV57401565; called by muse, mutect2, varscan2
- ARMC5 | c.2572A>T p.I858F | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0.299); catalogued as COSV51660045; called by muse, mutect2, varscan2
- ARMCX1 | c.496A>G p.S166G | Missense Mutation (SNP) | VAF 59/74 reads (80%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV65705577; called by muse, mutect2, varscan2
- ARMCX3 | c.265A>T p.R89* | Nonsense Mutation (SNP) | VAF 28/29 reads (97%) | catalogued as COSV57871663; called by muse, mutect2, varscan2
- ARRDC5 | c.154C>A p.P52T (on ENST00000381781; = p.P38T on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/111 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67788307; called by muse, mutect2, varscan2
- ART4 | c.835A>G p.N279D | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57453289; called by muse, mutect2, varscan2
- ASAH2 | c.154A>T p.T52S | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.014); catalogued as COSV61484438; called by muse, mutect2, varscan2
- ASAP1 | c.1720A>T p.R574W | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV63054475; called by muse, mutect2, varscan2
- ASIC1 | c.1094T>C p.M365T | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV57320048; called by muse, mutect2, varscan2
- ASIC1 | c.1377+2T>A p.X459_splice | Splice Site (SNP) | VAF 31/65 reads (48%) | catalogued as COSV57320217; called by muse, mutect2, varscan2
- ASTL | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.096); catalogued as COSV60905465; called by muse, varscan2
- ASTN1 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.272); catalogued as rs763087164, COSV56081649, COSV56085459; called by muse, mutect2, varscan2
- ATAD3A | c.494A>G p.K165R | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.534); catalogued as COSV100186632; called by muse, mutect2, varscan2
- ATOH1 | c.908C>A p.T303K | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV60038773; called by muse, mutect2, varscan2
- ATP13A4 | c.3272T>C p.I1091T | Missense Mutation (SNP) | VAF 140/323 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.811); catalogued as COSV61327237; called by muse, mutect2, varscan2
- ATP13A4 | c.230C>A p.T77K | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55075319; called by muse, mutect2, varscan2
- ATP1A2 | c.1004T>A p.L335Q | Missense Mutation (SNP) | VAF 74/102 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV63405932; called by muse, mutect2, varscan2
- ATP1A3 | c.2961-1G>T p.X987_splice (on ENST00000545399 / NM_001256214.2; = p.X974_splice on NM_152296.5) | Splice Site (SNP) | VAF 8/21 reads (38%) | catalogued as COSV57491260; called by muse, mutect2
- ATP1A4 | c.2101C>A p.P701T | Missense Mutation (SNP) | VAF 224/311 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV63628556; called by muse, mutect2, varscan2
- ATP2C1 | c.2068G>T p.E690* | Nonsense Mutation (SNP) | VAF 10/23 reads (43%) | catalogued as CM154426, COSV60752853, COSV60762794; called by muse, mutect2, varscan2
- ATP6V1A | c.1705A>G p.I569V | Missense Mutation (SNP) | VAF 68/162 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1159395947, COSV56364709; called by muse, mutect2, varscan2
- ATP8A2 | c.2677G>T p.E893* | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as COSV54976877; called by muse, mutect2, varscan2
- ATP8B1 | c.1867A>C p.T623P | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52180267; called by muse, mutect2, varscan2
- ATR | c.3905A>T p.H1302L | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.778); catalogued as COSV63392330; called by muse, mutect2, varscan2
- ATR | c.1053G>T p.Q351H | Missense Mutation (SNP) | VAF 89/179 reads (50%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as COSV63392338; called by muse, mutect2, varscan2
- ATRX | c.2503A>T p.R835* | Nonsense Mutation (SNP) | VAF 50/51 reads (98%) | catalogued as COSV64883373; called by muse, mutect2, varscan2
- AZIN2 | c.440A>T p.H147L | Missense Mutation (SNP) | VAF 60/145 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV53860727; called by muse, mutect2, varscan2
- B3GAT3 | c.428A>T p.Q143L | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as COSV53884557; called by muse, mutect2, varscan2
- B3GLCT | c.104A>G p.E35G | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs112402968, COSV58458774; called by muse, mutect2, varscan2
- B4GALNT3 | c.1555A>G p.S519G | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV56758060; called by muse, mutect2, varscan2
- B4GALNT3 | c.2825G>C p.G942A | Missense Mutation (SNP) | VAF 68/156 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56758070; called by muse, mutect2, varscan2
- BACH2 | c.814A>T p.R272W | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV57609100; called by muse, mutect2, varscan2
- BBS5 | c.629A>G p.K210R | Missense Mutation (SNP) | VAF 13/261 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.017); catalogued as rs1559124753, COSV54754329; called by muse, mutect2
- BBS7 | c.1481A>G p.H494R | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52659555; called by muse, mutect2, varscan2
- BCLAF1 | c.353G>A p.R118K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV62142019, COSV62145966; called by mutect2, varscan2
- BEND3 | c.1982A>G p.H661R | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV64682324; called by muse, mutect2, varscan2
- BFSP2 | c.848T>C p.V283A | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as COSV56591509; called by muse, mutect2, varscan2
- BICC1 | c.1048-2A>G p.X350_splice | Splice Site (SNP) | VAF 33/91 reads (36%) | catalogued as COSV54066997; called by muse, mutect2, varscan2
- BIRC6 | c.9059A>C p.H3020P | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); catalogued as COSV70205976; called by muse, mutect2, varscan2
- BIRC6 | c.11869A>C p.N3957H | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.357); catalogued as COSV70205983; called by muse, mutect2, varscan2
- BIRC7 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 44/47 reads (94%) | SIFT tolerated (0.62); PolyPhen benign (0.014); catalogued as rs768709953, COSV53903348; called by muse, mutect2, varscan2
- BLNK | c.590C>T p.S197L | Missense Mutation (SNP) | VAF 47/65 reads (72%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV56414008; called by muse, mutect2, varscan2
- BMPER | c.262T>C p.S88P | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV51831552; called by muse, mutect2, varscan2
- BPI | c.1229T>A p.L410H (on ENST00000262865; = p.L406H on NM_001725.3) | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53408490; called by muse, mutect2, varscan2
- BPIFA1 | c.335A>G p.D112G | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV62825223; called by muse, mutect2, varscan2
- BPIFB2 | c.576T>C p.I192= | Splice Region (SNP) | VAF 9/35 reads (26%) | catalogued as COSV50070933; called by muse, mutect2, varscan2
- BPIFC | c.1035G>T p.E345D | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.243); catalogued as COSV55915892; called by muse, mutect2, varscan2
- BPTF | c.4129A>G p.S1377G | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.026); catalogued as COSV58846888; called by muse, mutect2, varscan2
- BRD9 | c.1199A>T p.D400V | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV60250153; called by muse, mutect2, varscan2
- BRINP2 | c.462A>G p.G154= | Splice Region (SNP) | VAF 222/293 reads (76%) | catalogued as COSV64180304; called by muse, mutect2, varscan2
- BRIP1 | c.2380-2A>T p.X794_splice | Splice Site (SNP) | VAF 16/37 reads (43%) | catalogued as COSV52008919; called by muse, mutect2, varscan2
- BSG | c.299A>T p.E100V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV61078217; called by muse, mutect2, varscan2
- BUB1B | c.1379A>T p.Q460L | Missense Mutation (SNP) | VAF 116/268 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.65); catalogued as COSV55016644; called by muse, mutect2, varscan2
- C10orf71 | c.1511A>T p.K504M | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60513346; called by muse, mutect2, varscan2
- C11orf65 | c.817A>C p.I273L | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV67598664; called by muse, mutect2, varscan2
- C16orf54 | c.605A>T p.Q202L | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV61477280; called by muse, mutect2, varscan2
- C16orf89 | c.284T>A p.L95Q | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1224169796, COSV60126576; called by muse, mutect2, varscan2
- C1QTNF7 | c.628C>A p.L210M | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140339349; called by muse, mutect2, varscan2
- C21orf58 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 25/32 reads (78%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1302627599, COSV52451742; called by muse, mutect2, varscan2
- C2orf80 | c.137T>C p.L46S | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58019264; called by muse, mutect2, varscan2
- C3 | c.1526A>G p.E509G | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as COSV55581456; called by muse, mutect2, varscan2
- C3orf20 | c.2510T>C p.V837A | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0.04); catalogued as COSV53789365; called by muse, mutect2, varscan2
- CA9 | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.834); catalogued as COSV65676524; called by muse, mutect2, varscan2
- CAB39 | c.182A>T p.E61V | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as COSV51479343; called by muse, mutect2, varscan2
- CABCOCO1 | c.9C>A p.F3L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV57596309; called by mutect2, varscan2
- CABLES1 | c.1000A>G p.R334G (on ENST00000256925 / NM_001100619.2; = p.R69G on NM_138375.2) | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV56937487; called by muse, mutect2, varscan2
- CABP1 | c.989C>A p.A330D (on ENST00000316803 / NM_001033677.1; = p.A127D on NM_004276.5) | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56460420; called by muse, mutect2, varscan2
- CACHD1 | c.2976-2A>G p.X992_splice | Splice Site (SNP) | VAF 84/191 reads (44%) | catalogued as COSV51559995; called by muse, mutect2, varscan2
- CACNA1A | c.2291T>A p.V764E | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.099); catalogued as COSV64212475; called by muse, mutect2, varscan2
- CACNA1E | c.1124A>T p.Q375L | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV62424641; called by muse, mutect2, varscan2
- CACNA1E | c.6572A>T p.E2191V (on ENST00000367573 / NM_001205293.3; = p.E2148V on NM_000721.4) | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV62424742; called by muse, mutect2, varscan2
- CACNA1H | c.6139A>G p.R2047G | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as COSV52358417; called by muse, mutect2, varscan2
- CACNA2D4 | c.1715C>G p.P572R | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54960430; called by muse, mutect2, varscan2
- CACNA2D4 | c.165G>T p.W55C | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1284328591, COSV54960454; called by muse, mutect2, varscan2
- CACNG3 | c.866T>A p.L289Q | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV50083666; called by muse, mutect2, varscan2
- CADM1 | c.1051A>G p.T351A | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as COSV59023352; called by muse, mutect2, varscan2
- CADPS | c.1295A>G p.Q432R | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.272); catalogued as COSV51902969; called by muse, mutect2, varscan2
- CALD1 | c.191A>T p.D64V | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV62654119; called by muse, mutect2, varscan2
- CAMK2A | c.1386G>A p.W462* (on ENST00000348628 / NM_171825.2; = p.W473* on NM_015981.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 18/36 reads (50%) | catalogued as COSV62246950; called by muse, varscan2
- CAND1 | c.3175A>T p.R1059* | Nonsense Mutation (SNP) | VAF 41/106 reads (39%) | catalogued as COSV73389787; called by muse, mutect2, varscan2
- CAPS2 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs200022333, COSV60829115; called by muse, mutect2, varscan2
- CARD11 | c.586A>T p.K196* | Nonsense Mutation (SNP) | VAF 42/95 reads (44%) | catalogued as COSV62720051; called by muse, mutect2, varscan2
- CARD11 | c.23T>G p.M8R | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.206); catalogued as rs368132142; called by muse, mutect2, varscan2
- CASQ2 | c.1053T>A p.D351E | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs1557783756, COSV54774029; called by muse, mutect2, varscan2
- CAVIN2 | c.185T>A p.L62Q | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58425938; called by muse, mutect2, varscan2
- CCAR2 | c.2626C>G p.R876G | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV52386588; called by muse, mutect2, varscan2
- CCBE1 | c.607A>T p.K203* | Nonsense Mutation (SNP) | VAF 25/59 reads (42%) | catalogued as COSV67951572; called by muse, mutect2, varscan2
- CCDC102B | c.1394T>C p.V465A | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs756809241, COSV60154532; called by muse, mutect2, varscan2
- CCDC103 | c.452T>A p.L151Q | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53653761; called by muse, mutect2, varscan2
- CCDC113 | c.551A>T p.N184I | Missense Mutation (SNP) | VAF 76/85 reads (89%) | SIFT tolerated (0.25); PolyPhen benign (0.035); catalogued as COSV54687889, COSV54688442; called by muse, mutect2, varscan2
- CCDC136 | c.1751A>T p.E584V | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778362626, COSV52804970; called by muse, mutect2, varscan2
- CCDC178 | c.2381A>T p.K794M (on ENST00000383096 / NM_001105528.3; = p.K756M on NM_198995.3) | Missense Mutation (SNP) | VAF 97/191 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV55797699; called by muse, mutect2, varscan2
- CCDC198 | c.158A>G p.Q53R | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1431816495, COSV53603270; called by muse, mutect2, varscan2
- CCDC27 | c.1330G>T p.A444S | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV53903685; called by muse, mutect2, varscan2
- CCDC50 | c.317A>G p.E106G | Missense Mutation (SNP) | VAF 149/361 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV66669699; called by muse, mutect2, varscan2
- CCDC78 | c.908T>A p.L303Q | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV53497908; called by muse, mutect2, varscan2
- CCDC81 | c.726A>T p.K242N (on ENST00000445632 / NM_001156474.2; = p.K152N on NM_021827.4) | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.081); catalogued as COSV53581754; called by muse, mutect2, varscan2
- CCL11 | c.55C>A p.P19T | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59925681; called by muse, mutect2, varscan2
- CCNE2 | c.131A>T p.E44V | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV57377500; called by muse, mutect2, varscan2
- CCR6 | c.479C>A p.T160K | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV59476196; called by muse, mutect2, varscan2
- CCR7 | c.8T>A p.L3Q | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.013); catalogued as COSV55849588; called by muse, mutect2, varscan2
- CCR8 | c.581G>T p.W194L | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV58336657, COSV58338031; called by muse, mutect2, varscan2
- CCSER1 | c.1918A>G p.R640G | Missense Mutation (SNP) | VAF 62/112 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61417938, COSV61468898; called by muse, mutect2, varscan2
- CD276 | c.242A>G p.E81G | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV59205728; called by muse, mutect2, varscan2
- CD38 | c.857A>T p.Q286L | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV56893174; called by muse, mutect2, varscan2
- CD5L | c.859T>A p.C287S | Missense Mutation (SNP) | VAF 144/210 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63823120; called by muse, varscan2
- CD6 | c.44T>A p.L15H | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.635); catalogued as COSV57842796; called by muse, mutect2, varscan2
- CD86 | c.742T>C p.W248R (on ENST00000330540 / NM_175862.5; = p.W242R on NM_006889.4) | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV52610290; called by muse, mutect2, varscan2
- CDC14B | c.947-2A>G p.X316_splice | Splice Site (SNP) | VAF 129/147 reads (88%) | catalogued as COSV55794126, COSV99685514; called by muse, mutect2, varscan2
- CDC42BPG | c.2533A>T p.R845W | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV61349236; called by muse, mutect2, varscan2
- CDH15 | c.242G>C p.S81T | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV57027772; called by muse, mutect2, varscan2
- CDH20 | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 52/98 reads (53%) | catalogued as COSV53018145; called by muse, mutect2, varscan2
- CDH26 | c.1063A>G p.I355V | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.318); catalogued as rs547604097, COSV54854991; called by muse, mutect2, varscan2
- CDH5 | c.1451A>T p.Q484L | Missense Mutation (SNP) | VAF 42/49 reads (86%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV58519986; called by muse, mutect2, varscan2
- CDH6 | c.1280T>C p.M427T | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.348); catalogued as COSV54078482; called by muse, mutect2, varscan2
- CDK15 | c.280A>T p.S94C (on ENST00000652192 / NM_001366386.2; = p.S43C on NM_139158.2) | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.39); catalogued as COSV53638563; called by muse, mutect2, varscan2
- CDKL3 | c.973A>T p.R325W | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as COSV54741917, COSV54745019; called by muse, mutect2, varscan2
- CDX2 | c.149C>A p.A50E | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.246); catalogued as COSV66829927; called by muse, mutect2, varscan2
- CEACAM6 | c.747C>G p.Y249* | Nonsense Mutation (SNP) | VAF 41/101 reads (41%) | catalogued as rs782652072, COSV52269307; called by muse, mutect2, varscan2
- CEBPE | c.356C>A p.A119E | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as rs752134859, COSV52830766; called by muse, mutect2, varscan2
- CENPF | c.6008A>T p.Q2003L | Missense Mutation (SNP) | VAF 57/70 reads (81%) | SIFT deleterious (0.04); PolyPhen benign (0.34); catalogued as COSV65279043; called by muse, mutect2, varscan2
- CENPV | c.419A>G p.Q140R | Missense Mutation (SNP) | VAF 107/127 reads (84%) | SIFT tolerated (0.23); PolyPhen benign (0.048); catalogued as COSV55334117; called by muse, mutect2, varscan2
- CEP250 | c.1893C>G p.S631R | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV61174504; called by muse, mutect2, varscan2
- CEP290 | c.1469A>G p.E490G | Missense Mutation (SNP) | VAF 111/259 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as COSV58356337; called by muse, mutect2, varscan2
- CEP55 | c.81A>T p.L27F | Missense Mutation (SNP) | VAF 36/44 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65185926; called by muse, mutect2, varscan2
- CEP63 | c.894G>T p.K298N | Missense Mutation (SNP) | VAF 195/396 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as COSV59679392; called by muse, mutect2, varscan2
- CER1 | c.502A>T p.S168C | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV66603955; called by muse, mutect2, varscan2
- CERKL | c.1150A>T p.K384* (on ENST00000339098 / NM_001030311.2; = p.K358* on NM_201548.5) | Nonsense Mutation (SNP) | VAF 79/183 reads (43%) | catalogued as COSV59213693; called by muse, mutect2, varscan2
- CFAP206 | c.830A>T p.Q277L | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.173); catalogued as COSV51537178; called by muse, varscan2
- CFAP44 | c.2426T>C p.I809T | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV55615892; called by muse, mutect2, varscan2
- CFAP54 | c.5252T>C p.L1751P | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs967703619, COSV100733363; called by muse, mutect2, varscan2
- CFAP69 | c.1729G>T p.G577C | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV60188490; called by muse, mutect2, varscan2
- CFAP69 | c.2447A>G p.Q816R | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV60188501; called by muse, mutect2, varscan2
- CFAP74 | c.1906A>T p.T636S | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV54573991; called by muse, mutect2, varscan2
- CFAP74 | c.1072A>G p.R358G | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV54574004; called by muse, mutect2, varscan2
- CFH | c.3355del p.D1119Tfs*32 | Frame Shift Del (DEL) | VAF 74/87 reads (85%) | catalogued as COSV66407261; called by mutect2, varscan2
- CHD1L | c.1511A>T p.Q504L | Missense Mutation (SNP) | VAF 96/121 reads (79%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs782743019, COSV63615358; called by muse, mutect2, varscan2
- CHEK2 | c.70A>T p.S24C | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.35); catalogued as COSV60426438; called by muse, mutect2, varscan2
- CHL1 | c.305A>T p.H102L | Missense Mutation (SNP) | VAF 78/153 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.371); catalogued as rs1440567668, COSV56606449; called by muse, mutect2, varscan2
- CHPF | c.610A>T p.T204S | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.421); catalogued as COSV60536769; called by muse, mutect2, varscan2
- CHRM2 | c.1315T>A p.C439S | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57784877; called by muse, mutect2, varscan2
- CIC | c.1099G>C p.E367Q | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.815); catalogued as COSV50563036, COSV50665133; called by muse, mutect2, varscan2
- CILP2 | c.1766G>T p.G589V | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT tolerated (0.15); PolyPhen benign (0.147); catalogued as COSV52280530; called by muse, mutect2, varscan2
- CKAP2L | c.105-2A>T p.X35_splice | Splice Site (SNP) | VAF 107/254 reads (42%) | catalogued as COSV56698268; called by muse, mutect2, varscan2
- CKMT1A | c.983T>G p.V328G | Missense Mutation (SNP) | VAF 78/208 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100787741; called by muse, mutect2, varscan2
- CLASP2 | c.4235A>G p.D1412G (on ENST00000359576; = p.D1411G on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.407); catalogued as rs953040113, COSV56294004; called by muse, mutect2, varscan2
- CLCA1 | c.2062G>T p.V688L | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52331364; called by muse, mutect2, varscan2
- CLDN16 | c.140G>T p.W47L | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM001068, COSV53229343; called by muse, mutect2, varscan2
- CLEC16A | c.1031A>T p.E344V | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1278193295, COSV68501994; called by muse, mutect2, varscan2
- CLEC2B | c.433A>T p.R145W | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV57310626; called by muse, varscan2
- CLK2 | c.1147-2A>T p.X383_splice (on ENST00000368361 / NM_001294339.2; = p.X382_splice on NM_003993.4) | Splice Site (SNP) | VAF 229/329 reads (70%) | catalogued as COSV56947436; called by muse, mutect2, varscan2
- CLSTN1 | c.1901C>T p.T634I (on ENST00000377298 / NM_001009566.3; = p.T624I on NM_014944.4) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs750303998, COSV63651106; called by muse, mutect2, varscan2
- CMTM4 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 28/33 reads (85%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.999); catalogued as COSV58063718; called by muse, mutect2, varscan2
- CNBD1 | c.143T>A p.I48N | Missense Mutation (SNP) | VAF 116/261 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV72917592; called by muse, varscan2
- CNBP | c.88A>T p.R30* | Nonsense Mutation (SNP) | VAF 131/277 reads (47%) | catalogued as COSV69654997; called by muse, mutect2, varscan2
- CNGA3 | c.200G>T p.G67V | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as COSV55628276; called by muse, mutect2, varscan2
- CNR2 | c.1057A>G p.R353G | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV65694639; called by muse, mutect2
- CNTN6 | c.2509G>T p.G837C | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63189806; called by muse, mutect2, varscan2
- CNTNAP4 | c.1904A>T p.Q635L | Missense Mutation (SNP) | VAF 38/47 reads (81%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as COSV56700368; called by muse, mutect2, varscan2
- CNTNAP5 | c.385T>A p.F129I | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV70512246; called by muse, mutect2, varscan2
- COL11A1 | c.2295G>A p.K765= | Splice Region (SNP) | VAF 59/145 reads (41%) | catalogued as COSV62197657, COSV62201337; called by muse, mutect2, varscan2
- COL11A2 | c.2217T>C p.G739= (on ENST00000341947 / NM_080680.3; = p.G632= on NM_080679.2) | Splice Region (SNP) | VAF 23/85 reads (27%) | catalogued as COSV59502620; called by muse, mutect2, varscan2
- COL16A1 | c.944A>T p.E315V | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV54713875; called by muse, mutect2, varscan2
- COL6A2 | c.2732T>A p.L911Q | Missense Mutation (SNP) | VAF 20/22 reads (91%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.982); catalogued as COSV52429954; called by muse, mutect2, varscan2
- COL6A3 | c.5347T>A p.S1783T | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.233); catalogued as COSV55093755, COSV55110016; called by muse, mutect2, varscan2
- COL6A6 | c.92T>C p.L31S | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62037801; called by muse, mutect2, varscan2
- COL6A6 | c.1153C>A p.Q385K | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV62037818; called by muse, mutect2, varscan2
- COL9A1 | c.2561C>A p.P854H | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57890187; called by muse, mutect2, varscan2
- COL9A2 | c.1487G>A p.G496D | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65622468, COSV65624106; called by muse, mutect2, varscan2
- COL9A2 | c.518T>C p.L173P | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as rs1396260028, COSV65608123; called by muse, mutect2, varscan2
- COL9A2 | c.364-2A>T p.X122_splice | Splice Site (SNP) | VAF 22/61 reads (36%) | catalogued as COSV65608126; called by muse, mutect2
- CORO2B | c.702G>T p.M234I | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV55953038; called by muse, mutect2, varscan2
- CPB1 | c.377A>T p.E126V | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated (0.52); PolyPhen benign (0.019); catalogued as COSV51577037; called by muse, varscan2
- CPVL | c.964-2A>T p.X322_splice | Splice Site (SNP) | VAF 28/67 reads (42%) | catalogued as COSV55308679; called by muse, mutect2, varscan2
- CREB3L1 | c.1029C>A p.N343K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55833149, COSV55833195; called by muse, mutect2, varscan2
- CRYBA4 | c.495A>T p.E165D | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61322955; called by muse, mutect2, varscan2
- CRYBB1 | c.680A>T p.Q227L | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV53234757; called by muse, mutect2, varscan2
- CSDE1 | c.906A>T p.K302N (on ENST00000358528 / NM_001007553.3; = p.K271N on NM_007158.6) | Missense Mutation (SNP) | VAF 98/204 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54759723; called by muse, mutect2, varscan2
- CSMD1 | c.9253A>T p.R3085W (on ENST00000520002; = p.R3084W on NM_033225.6) | Missense Mutation (SNP) | VAF 41/57 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV59383462; called by muse, mutect2, varscan2
- CSMD1 | c.7445A>T p.Y2482F (on ENST00000520002; = p.Y2481F on NM_033225.6) | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as COSV59383484; called by muse, mutect2, varscan2
- CSMD1 | c.6841G>T p.D2281Y (on ENST00000520002; = p.D2280Y on NM_033225.6) | Missense Mutation (SNP) | VAF 37/47 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59288692, COSV59383511; called by muse, mutect2, varscan2
- CSMD2 | c.4273T>A p.C1425S | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV53963646; called by muse, mutect2, varscan2
- CSMD2 | c.4045A>T p.K1349* | Nonsense Mutation (SNP) | VAF 51/90 reads (57%) | catalogued as COSV53963664; called by muse, mutect2, varscan2
- CSMD2 | c.2674A>T p.S892C | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV53963685; called by muse, mutect2, varscan2
- CSN3 | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 79/260 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.092); catalogued as COSV59245049; called by muse, mutect2, varscan2
- CTNND2 | c.2520G>T p.M840I | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV58870486; called by muse, mutect2, varscan2
- CTNND2 | c.2177G>T p.G726V | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58924817, COSV58934827; called by muse, mutect2, varscan2
- CTSC | c.517A>T p.N173Y | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV57060373; called by muse, mutect2, varscan2
- CUBN | c.1089T>A p.D363E | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64715136; called by muse, mutect2, varscan2
- CXCL1 | c.121C>A p.L41M | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67611901; called by muse, mutect2, varscan2
- CYB561A3 | c.77A>T p.Y26F | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT tolerated (0.37); PolyPhen benign (0.034); catalogued as COSV53653959; called by muse, mutect2, varscan2
- CYLC2 | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 55/67 reads (82%) | SIFT deleterious (0.02); PolyPhen benign (0.264); catalogued as COSV66336461, COSV66339631; called by muse, varscan2
- CYLC2 | c.467A>C p.D156A | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV66339638; called by muse, varscan2
- CYP21A2 | c.578A>G p.K193R | Missense Mutation (SNP) | VAF 142/539 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV64489022; called by muse, mutect2, varscan2
- DAB2IP | c.925A>C p.K309Q (on ENST00000408936; = p.K281Q on NM_032552.3) | Missense Mutation (SNP) | VAF 21/26 reads (81%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.987); catalogued as COSV52268003; called by muse, mutect2, varscan2
- DACH2 | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 165/185 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64185901; called by muse, mutect2, varscan2
- DAO | c.461A>T p.E154V | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as COSV57324581; called by muse, mutect2, varscan2
- DCAF11 | c.262G>T p.G88W | Missense Mutation (SNP) | VAF 65/139 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58110730; called by muse, mutect2, varscan2
- DCHS1 | c.3347A>T p.E1116V | Missense Mutation (SNP) | VAF 27/28 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55042862; called by muse, mutect2, varscan2
- DDB1 | c.892A>T p.K298* | Nonsense Mutation (SNP) | VAF 71/160 reads (44%) | catalogued as COSV57105771; called by muse, mutect2, varscan2
- DDHD1 | c.1822A>T p.S608C (on ENST00000323669; = p.S805C on NM_030637.3) | Missense Mutation (SNP) | VAF 60/126 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV60362730; called by muse, varscan2
- DDRGK1 | c.409-2A>C p.X137_splice | Splice Site (SNP) | VAF 26/65 reads (40%) | catalogued as COSV63227455; called by muse, mutect2, varscan2
- DDX20 | c.1280A>G p.Q427R | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as COSV63831623; called by muse, mutect2, varscan2
- DDX46 | c.602A>G p.E201G | Missense Mutation (SNP) | VAF 64/108 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV62801057; called by muse, mutect2, varscan2
- DDX50 | c.532A>T p.I178L | Missense Mutation (SNP) | VAF 100/181 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.31); catalogued as COSV65293366; called by muse, mutect2, varscan2
- DDX53 | c.1453A>G p.S485G | Missense Mutation (SNP) | VAF 70/76 reads (92%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60070016; called by muse, mutect2, varscan2
- DDX60L | c.4444G>T p.A1482S | Missense Mutation (SNP) | VAF 80/238 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as COSV52721932, COSV52723547; called by muse, mutect2, varscan2
- DEFB113 | c.32T>C p.V11A | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.108); catalogued as COSV67143595; called by muse, mutect2, varscan2
- DENND1C | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.115); catalogued as COSV67375304; called by muse, mutect2, varscan2
- DENND2A | c.238G>T p.V80L | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV99327043; called by muse, mutect2, varscan2
- DES | c.978C>A p.H326Q | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV64661056; called by muse, mutect2, varscan2
- DHRS7C | c.935G>T p.G312V (on ENST00000330255 / NM_001220493.2; = p.G311V on NM_001105571.3) | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV57652808; called by muse, mutect2, varscan2
- DIP2C | c.3086A>T p.H1029L | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as COSV55179176; called by muse, mutect2, varscan2
- DIS3L2 | c.937A>G p.N313D | Missense Mutation (SNP) | VAF 59/120 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.085); catalogued as COSV56063702; called by muse, mutect2, varscan2
- DISP2 | c.2545A>T p.S849C | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV51143541; called by muse, mutect2, varscan2
- DKC1 | c.769A>G p.K257E | Missense Mutation (SNP) | VAF 26/29 reads (90%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV65778213; called by muse, mutect2, varscan2
- DLG5 | c.1390A>G p.T464A | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.76); PolyPhen benign (0.107); catalogued as COSV64949976; called by muse, mutect2, varscan2
- DMBT1 | c.7511A>G p.Y2504C (on ENST00000338354 / NM_001377530.1; = p.Y1747C on NM_004406.3) | Missense Mutation (SNP) | VAF 49/66 reads (74%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.614); catalogued as COSV57562361; called by muse, mutect2, varscan2
- DNAH10 | c.2303G>A p.G768E (on ENST00000409039; = p.G707E on NM_207437.3) | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (0.52); PolyPhen benign (0.139); catalogued as rs571838812, COSV69000138; called by muse, mutect2, varscan2
- DNAH10 | c.9323T>A p.L3108Q (on ENST00000409039; = p.L3047Q on NM_207437.3) | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV69001701; called by muse, mutect2, varscan2
- DNAH3 | c.1400A>C p.H467P | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as COSV54551901; called by muse, mutect2, varscan2
- DNAH8 | c.4499A>G p.Y1500C | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59480687; called by muse, mutect2, varscan2
- DNAH9 | c.11653G>A p.D3885N | Missense Mutation (SNP) | VAF 31/37 reads (84%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.735); catalogued as COSV52376992; called by muse, mutect2, varscan2
- DNAJB6 | c.316G>T p.G106* | Nonsense Mutation (SNP) | VAF 26/55 reads (47%) | catalogued as COSV51100399; called by muse, mutect2, varscan2
- DNAJC13 | c.53A>G p.H18R | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV53458220; called by muse, mutect2, varscan2
- DNM3 | c.911T>C p.L304S | Missense Mutation (SNP) | VAF 117/522 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62467279; called by muse, mutect2, varscan2
- DOCK10 | c.6290T>G p.L2097W | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51427824; called by muse, mutect2, varscan2
- DOCK2 | c.2129A>T p.Y710F | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV56988230; called by muse, mutect2, varscan2
- DOCK2 | c.2459A>C p.Y820S | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.273); catalogued as COSV56988240; called by muse, mutect2, varscan2
- DOP1B | c.481A>T p.I161F | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.971); catalogued as COSV54281690; called by muse, mutect2, varscan2
- DOP1B | c.2518A>G p.S840G | Missense Mutation (SNP) | VAF 70/149 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV67696158; called by muse, mutect2, varscan2
- DPP4 | c.2194G>T p.A732S | Missense Mutation (SNP) | VAF 82/170 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.08); catalogued as COSV62109862; called by muse, mutect2, varscan2
- DRAP1 | c.513-2A>T p.X171_splice | Splice Site (SNP) | VAF 77/140 reads (55%) | catalogued as COSV56989813; called by muse, mutect2, varscan2
- DSE | c.428A>G p.D143G | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV59067372; called by mutect2, varscan2
- DSG3 | c.388C>A p.L130I | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.817); catalogued as COSV57129701; called by muse, mutect2, varscan2
- DTNA | c.1640A>T p.E547V | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52026259; called by muse, mutect2, varscan2
- DTX3 | c.374T>A p.L125H | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV54090687; called by muse, mutect2, varscan2
- DYDC1 | c.323C>G p.A108G | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV64723442; called by muse, mutect2, varscan2
- DYNC2H1 | c.305A>T p.E102V | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV62106820; called by muse, mutect2, varscan2
- DYNC2H1 | c.2758G>T p.D920Y | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62094760, COSV62106828; called by muse, mutect2, varscan2
- DZIP3 | c.2782-2A>T p.X928_splice | Splice Site (SNP) | VAF 89/192 reads (46%) | catalogued as COSV64313889; called by muse, varscan2
- DZIP3 | c.2876A>T p.E959V | Missense Mutation (SNP) | VAF 82/184 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.541); catalogued as COSV64313890; called by muse, varscan2
- E4F1 | c.731-2A>C p.X244_splice | Splice Site (SNP) | VAF 20/34 reads (59%) | catalogued as COSV57041376; called by muse, mutect2, varscan2
- ECSCR | c.212C>A p.T71N | Missense Mutation (SNP) | VAF 52/87 reads (60%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.463); catalogued as COSV72928905; called by muse, mutect2, varscan2
- ECT2L | c.487A>G p.T163A | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs1207597984, COSV62887229; called by muse, mutect2, varscan2
- EDAR | c.671A>T p.H224L | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV51507854; called by muse, mutect2, varscan2
- EDC4 | c.202A>G p.T68A | Missense Mutation (SNP) | VAF 24/28 reads (86%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV54647466; called by muse, mutect2, varscan2
- EDEM2 | c.854A>G p.K285R | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV65713692; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2537G>T p.S846I | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755379422, COSV62568580; called by muse, mutect2, varscan2
- EFL1 | c.2699G>A p.S900N | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV51610028; called by muse, mutect2, varscan2
- EHMT1 | c.2617G>T p.G873C | Missense Mutation (SNP) | VAF 42/55 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71778699; called by muse, mutect2, varscan2
- EIF3D | c.305A>T p.Q102L | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV53405443; called by muse, mutect2, varscan2
- ELFN2 | c.2224A>T p.T742S | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV68746512; called by muse, mutect2, varscan2
- ELMOD2 | c.171+2T>C p.X57_splice | Splice Site (SNP) | VAF 110/244 reads (45%) | catalogued as COSV60271536; called by muse, mutect2, varscan2
- ELSPBP1 | c.343T>G p.C115G | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60415016; called by muse, mutect2, varscan2
- EN1 | c.1044G>T p.K348N | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54632602; called by muse, mutect2, varscan2
- EPB41L3 | c.2960A>G p.Y987C | Missense Mutation (SNP) | VAF 30/36 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157621999, COSV59467905; called by muse, mutect2, varscan2
- EPB42 | c.923A>G p.Y308C (on ENST00000441366 / NM_001114134.2; = p.Y338C on NM_000119.3) | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs778870883, COSV55751725; called by muse, mutect2, varscan2
- EPHB3 | c.2246T>A p.L749Q | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV57809115; called by muse, mutect2, varscan2
- EPS15 | c.2032A>G p.N678D | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV65545374; called by muse, mutect2
- ERI3 | c.889G>T p.G297C | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.923); catalogued as COSV64833702; called by muse, mutect2, varscan2
- ERICH3 | c.1540A>G p.N514D | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.292); catalogued as COSV58618526; called by muse, mutect2, varscan2
- ERICH6 | c.1199A>C p.Q400P | Missense Mutation (SNP) | VAF 82/216 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as COSV55803302; called by muse, mutect2, varscan2
- ESM1 | c.247T>G p.C83G | Missense Mutation (SNP) | VAF 47/82 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67318946; called by muse, mutect2, varscan2
- EXOSC7 | c.527G>C p.G176A | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.465); catalogued as COSV55557849; called by muse, mutect2, varscan2
- F2RL3 | c.248T>A p.L83H | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV50186652; called by muse, mutect2, varscan2
- F5 | c.1277A>T p.Q426L | Missense Mutation (SNP) | VAF 129/173 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63126471; called by muse, mutect2, varscan2
- FAM120B | c.1158G>T p.R386S | Missense Mutation (SNP) | VAF 74/157 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as rs201916124, COSV53008435; called by muse, mutect2, varscan2
- FAM131B | c.535G>T p.A179S | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (0.71); PolyPhen benign (0.011); catalogued as COSV58368336, COSV58374485; called by muse, mutect2, varscan2
- FAM168B | c.301G>A p.G101S | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.994); catalogued as COSV66304811; called by muse, mutect2, varscan2
- FAM181A | c.716T>A p.L239Q | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.466); catalogued as COSV50891608; called by muse, mutect2, varscan2
- FAM227B | c.552A>C p.R184S | Missense Mutation (SNP) | VAF 110/259 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV54819512; called by muse, mutect2, varscan2
- FAM47C | c.1417C>T p.H473Y | Missense Mutation (SNP) | VAF 44/48 reads (92%) | SIFT tolerated, low confidence (0.5); PolyPhen probably damaging (0.958); catalogued as COSV100792932, COSV63723569; called by muse, mutect2, varscan2
- FAM71B | c.57T>A p.S19R | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV57231282; called by muse, mutect2, varscan2
- FAM83H | c.2984A>T p.Q995L | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as COSV62030202; called by muse, mutect2, varscan2
- FAM9A | c.157A>T p.R53W | Missense Mutation (SNP) | VAF 57/64 reads (89%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.427); catalogued as COSV66813347, COSV66813755; called by muse, mutect2, varscan2
- FAN1 | c.203A>T p.D68V | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.109); catalogued as rs772421002, COSV62952176; called by muse, mutect2, varscan2
- FANCM | c.5042A>T p.N1681I | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.212); catalogued as COSV57506663; called by muse, mutect2, varscan2
- FAT2 | c.2639A>C p.H880P | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55829479; called by muse, mutect2, varscan2
- FAT2 | c.2369T>C p.V790A | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as COSV55829494; called by muse, mutect2
- FAT3 | c.4453A>T p.T1485S | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV53174269; called by muse, mutect2, varscan2
- FAT4 | c.4384C>A p.Q1462K | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as COSV67900258; called by muse, varscan2
- FAT4 | c.4513A>T p.I1505L | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as COSV67900266; called by muse, varscan2
- FAT4 | c.5438T>C p.L1813P | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV58708877; called by muse, mutect2, varscan2
- FBN1 | c.5026C>A p.P1676T | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV57330541; called by muse, mutect2, varscan2
- FBN3 | c.4204T>A p.C1402S | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54473142; called by muse, mutect2, varscan2
- FBXO27 | c.607A>T p.R203* | Nonsense Mutation (SNP) | VAF 23/78 reads (29%) | catalogued as COSV53073159; called by muse, mutect2, varscan2
- FBXW10 | c.856T>C p.S286P | Missense Mutation (SNP) | VAF 104/333 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57322336; called by muse, mutect2, varscan2
- FCRL5 | c.2692A>T p.T898S | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as COSV62520318; called by muse, mutect2, varscan2
- FCRL5 | c.737A>T p.Q246L | Missense Mutation (SNP) | VAF 185/255 reads (73%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.814); catalogued as COSV62520330; called by muse, mutect2, varscan2
- FER1L6 | c.643A>T p.T215S | Missense Mutation (SNP) | VAF 88/202 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV67552827; called by muse, mutect2, varscan2
- FER1L6 | c.1516A>G p.I506V | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs769712506, COSV67552828; called by muse, mutect2, varscan2
- FHDC1 | c.2597C>A p.S866Y | Missense Mutation (SNP) | VAF 78/163 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as COSV52602981; called by muse, mutect2, varscan2
- FKBP4 | c.824A>G p.E275G | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as rs1341405720, COSV50010041; called by muse, mutect2, varscan2
- FLG | c.8198G>T p.G2733V | Missense Mutation (SNP) | VAF 41/534 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.879); catalogued as rs777165664, COSV100912259; called by muse, mutect2
- FLG | c.475A>G p.K159E | Missense Mutation (SNP) | VAF 79/109 reads (72%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.543); catalogued as COSV64249211, COSV64249383; called by muse, mutect2, varscan2
- FLRT2 | c.1229A>G p.D410G | Missense Mutation (SNP) | VAF 73/176 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as COSV58150294; called by muse, mutect2, varscan2
- FLT3 | c.2054-2A>G p.X685_splice | Splice Site (SNP) | VAF 27/50 reads (54%) | catalogued as COSV54070242; called by muse, mutect2, varscan2
- FLT4 | c.3687-2A>T p.X1229_splice | Splice Site (SNP) | VAF 17/46 reads (37%) | catalogued as COSV56113099; called by muse, mutect2, varscan2
- FMN1 | c.4119A>G p.I1373M (on ENST00000616417 / NM_001277313.2; = p.I1150M on NM_001103184.4) | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); catalogued as COSV57933756; called by muse, mutect2, varscan2
- FMO2 | c.1136T>C p.F379S | Missense Mutation (SNP) | VAF 77/109 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV52950426; called by muse, mutect2, varscan2
- FNDC3A | c.3437A>T p.Q1146L (on ENST00000492622 / NM_001079673.2; = p.Q1090L on NM_014923.5) | Missense Mutation (SNP) | VAF 119/129 reads (92%) | SIFT tolerated (0.11); PolyPhen benign (0.25); catalogued as COSV68135114; called by muse, mutect2, varscan2
- FNIP1 | c.353A>T p.Q118L | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as COSV57200739; called by muse, mutect2, varscan2
- FOLR1 | c.715T>A p.W239R | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV56617201; called by muse, mutect2, varscan2
- FOS | c.997A>T p.S333C | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV57840424; called by muse, mutect2, varscan2
- FOXJ1 | c.1203G>T p.E401D | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as COSV59863008; called by muse, mutect2, varscan2
- FOXK1 | c.1022A>G p.Y341C | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs760221038, COSV61068760; called by muse, mutect2, varscan2
- FOXS1 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV54068348; called by muse, mutect2, varscan2
- FRAS1 | c.2671A>T p.S891C | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.765); catalogued as COSV53648275; called by muse, mutect2, varscan2
- FRAS1 | c.7490A>T p.Q2497L | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99355998; called by muse, varscan2
- FRAS1 | c.11230T>A p.Y3744N | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53648318; called by muse, mutect2, varscan2
- FREM1 | c.2900A>G p.E967G | Missense Mutation (SNP) | VAF 79/107 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66530161; called by muse, mutect2, varscan2
- FREM2 | c.5729T>A p.V1910E | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV54852560; called by muse, mutect2, varscan2
- FRY | c.6364A>T p.S2122C | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.044); catalogued as COSV66580220; called by muse, mutect2, varscan2
- FRY | c.8076G>C p.M2692I | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV66580228; called by muse, mutect2, varscan2
- FSIP2 | c.17941A>G p.K5981E | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.96); catalogued as COSV58099688; called by muse, mutect2, varscan2
- FSTL5 | c.155T>A p.V52D | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV60230268; called by muse, mutect2, varscan2
- FXYD4 | c.130T>G p.C44G | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.302); catalogued as COSV72052750; called by muse, mutect2, varscan2
- FYCO1 | c.541A>G p.R181G | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as rs773759736, COSV56119643; called by muse, mutect2, varscan2
- FZD2 | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59530272; called by muse, mutect2, varscan2
- GABRG1 | c.184G>T p.G62* | Nonsense Mutation (SNP) | VAF 61/118 reads (52%) | catalogued as COSV54961875; called by muse, mutect2, varscan2
- GALC | c.1940A>T p.D647V | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV54330366; called by muse, mutect2, varscan2
- GALNT16 | c.37A>T p.T13S | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.935); catalogued as COSV61888071; called by muse, mutect2, varscan2
- GALNT17 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 50/91 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs781199608, COSV61153886, COSV61176768; called by muse, mutect2, varscan2
- GALNT17 | c.1040T>G p.M347R | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV61191999; called by muse, mutect2, varscan2
- GALNTL6 | c.619A>G p.K207E | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.5); catalogued as COSV72493806; called by muse, mutect2, varscan2
- GAPVD1 | c.4299A>G p.A1433= (on ENST00000394104; = p.A1442= on NM_015635.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 22/29 reads (76%) | catalogued as COSV52927481; called by muse, mutect2, varscan2
- GATA6 | c.1220G>A p.G407D | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV52527067, COSV52527949; called by muse, mutect2, varscan2
- GCN1 | c.3098A>T p.E1033V | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.285); catalogued as COSV56114826; called by muse, mutect2, varscan2
- GEMIN5 | c.2323A>G p.N775D | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as rs1340413249, COSV53564917; called by muse, mutect2, varscan2
- GGPS1 | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 44/53 reads (83%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.727); catalogued as COSV51397867; called by muse, mutect2, varscan2
- GGT5 | c.257T>A p.M86K | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); catalogued as COSV54072509; called by muse, mutect2, varscan2
- GHDC | c.124G>T p.G42W | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.514); catalogued as COSV56989919; called by muse, mutect2, varscan2
- GIMAP4 | c.459C>A p.F153L | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.982); catalogued as COSV55434657; called by muse, mutect2, varscan2
- GJA8 | c.758A>T p.H253L | Missense Mutation (SNP) | VAF 125/169 reads (74%) | SIFT tolerated (0.46); PolyPhen benign (0.301); catalogued as COSV53790663; called by muse, mutect2, varscan2
- GLIPR1L1 | c.104A>T p.D35V | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as COSV56883935; called by muse, mutect2, varscan2
- GLP1R | c.566T>A p.L189Q | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64716420; called by muse, mutect2, varscan2
- GLP2R | c.1096A>G p.I366V | Missense Mutation (SNP) | VAF 32/45 reads (71%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV52329644; called by muse, mutect2, varscan2
- GLRA3 | c.1226T>A p.V409E | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1184281780, COSV56870321, COSV99928145; called by muse, mutect2, varscan2
- GMIP | c.586A>G p.K196E | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV52559948; called by muse, mutect2, varscan2
- GNB1L | c.236A>T p.Q79L | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.048); catalogued as COSV61548808, COSV61549976; called by muse, mutect2, varscan2
- GP6 | c.573G>T p.W191C | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59979704; called by muse, mutect2, varscan2
- GPR137C | c.975G>T p.Q325H | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.98); catalogued as COSV58707060; called by muse, mutect2, varscan2
- GPR139 | c.36C>G p.S12R | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV58505110; called by muse, mutect2, varscan2
- GPR149 | c.1139A>G p.Q380R | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67670112; called by muse, varscan2
- GPR149 | c.1123A>G p.I375V | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs765980219, COSV67667265; called by muse, varscan2
- GPR158 | c.3259C>A p.L1087I | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV66282575; called by muse, mutect2, varscan2
- GPR173 | c.650T>C p.M217T | Missense Mutation (SNP) | VAF 26/29 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60238262; called by muse, mutect2, varscan2
- GPR65 | c.999A>T p.L333F | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV50864390; called by muse, mutect2, varscan2
- GPR83 | c.691C>A p.P231T | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.615); catalogued as COSV54720813; called by muse, mutect2, varscan2
- GPR85 | c.708T>A p.S236R | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV51783920, COSV51785381; called by muse, mutect2, varscan2
- GPRC5A | c.470T>C p.M157T | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.629); catalogued as COSV50008759; called by muse, mutect2, varscan2
- GPSM3 | c.183G>T p.Q61H | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.969); catalogued as COSV66683778; called by muse, mutect2, varscan2
- GRAMD2A | c.764T>C p.V255A | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV59035276; called by muse, mutect2, varscan2
- GRHL2 | c.1046A>G p.E349G | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52545245, COSV52554896; called by muse, mutect2, varscan2
- GRIA4 | c.599A>T p.E200V | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV56919712; called by muse, mutect2, varscan2
- GRIA4 | c.835T>A p.W279R | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); catalogued as COSV56919728; called by muse, mutect2, varscan2
- GRID2 | c.2063A>G p.Y688C | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56266745; called by muse, mutect2, varscan2
- GRK1 | c.734T>A p.V245E | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59554252; called by muse, mutect2, varscan2
- GRXCR1 | c.668T>A p.L223Q | Missense Mutation (SNP) | VAF 81/197 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1171186208, COSV67674786; called by muse, mutect2, varscan2
- GYS1 | c.1795A>G p.K599E | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.519); catalogued as COSV54405407; called by muse, mutect2, varscan2
- H2AC14 | c.126G>T p.E42D | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as COSV100297687; called by muse, mutect2, varscan2
- H2AC20 | c.245G>C p.R82P | Missense Mutation (SNP) | VAF 115/363 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); catalogued as COSV58613207, COSV58613590; called by muse, mutect2, varscan2
- HABP4 | c.1016A>G p.Y339C | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs949638321, COSV64515333; called by muse, mutect2, varscan2
- HARS1 | c.1160A>G p.E387G | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV56909373; called by muse, mutect2, varscan2
- HAUS1 | c.622A>G p.M208V | Missense Mutation (SNP) | VAF 76/176 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs1359770078, COSV56364161; called by muse, mutect2, varscan2
- HCN4 | c.3602C>A p.S1201Y | Missense Mutation (SNP) | VAF 61/137 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV56087448; called by muse, mutect2, varscan2
- HEBP1 | c.265A>T p.N89Y | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV50009779; called by muse, mutect2, varscan2
- HECTD4 | c.1642A>C p.T548P | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66399917; called by muse, mutect2, varscan2
- HEMGN | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 20/65 reads (31%) | catalogued as COSV52326997, COSV52328246; called by muse, mutect2, varscan2
- HEMK1 | c.611A>T p.Q204L | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as COSV51752058; called by muse, mutect2, varscan2
- HEPHL1 | c.1383C>G p.I461M | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV59896323, COSV59896504; called by muse, mutect2, varscan2
- HERPUD2 | c.119A>T p.H40L | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV60947382; called by muse, mutect2, varscan2
- HFM1 | c.272A>T p.Q91L | Missense Mutation (SNP) | VAF 68/163 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV54037405; called by muse, mutect2, varscan2
- HGFAC | c.1186A>T p.R396W | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); catalogued as COSV66977315; called by muse, mutect2, varscan2
- HIP1 | c.869A>T p.Q290L | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as COSV61191534; called by muse, mutect2, varscan2
- HIVEP3 | c.5242G>A p.G1748S | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748302850, COSV56023726; called by muse, mutect2, varscan2
- HM13 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.444); catalogued as COSV59439612; called by muse, mutect2, varscan2
- HNRNPA3 | c.746A>G p.Y249C | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.171); catalogued as COSV66821186; called by muse, mutect2, varscan2
- HNRNPR | c.1505G>T p.R502I | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.272); catalogued as COSV56421033, COSV56424320; called by muse, mutect2, varscan2
- HOXA13 | c.736A>G p.M246V | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV56084259; called by muse, mutect2, varscan2
- HOXA2 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56067784, COSV56068432; called by muse, mutect2, varscan2
- HOXB6 | c.7T>A p.S3T | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53314263; called by muse, mutect2, varscan2
- HOXC10 | c.575T>A p.L192Q | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT tolerated (0.58); PolyPhen benign (0.143); catalogued as COSV57727103; called by muse, mutect2, varscan2
- HPS4 | c.2057A>C p.Q686P | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61105751; called by muse, mutect2, varscan2
- HS3ST4 | c.938T>G p.V313G | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.905); catalogued as COSV58830973; called by muse, mutect2, varscan2
- HTR7 | c.1388T>A p.L463* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as COSV53293045; called by muse, mutect2, varscan2
- HUS1 | c.559G>T p.D187Y | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV51840509; called by muse, mutect2, varscan2
- HYDIN | c.5947C>A p.L1983M | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.848); catalogued as COSV59270336; called by muse, mutect2, varscan2
- ICA1 | c.1316A>T p.Q439L | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV55584380; called by muse, mutect2, varscan2
- IFNA5 | c.245A>C p.E82A | Missense Mutation (SNP) | VAF 63/93 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52387580; called by muse, mutect2, varscan2
- IFNA8 | c.41T>A p.L14H | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV66505046; called by muse, mutect2, varscan2
- IFNB1 | c.279A>C p.Q93H | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV66525705; called by muse, mutect2, varscan2
- IGF1R | c.3197T>A p.L1066Q | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51385251; called by muse, mutect2, varscan2
- IGF2R | c.2510A>G p.D837G | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.096); catalogued as COSV63632752; called by muse, mutect2, varscan2
- IGFBP4 | c.673A>G p.K225E | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV54098510; called by muse, mutect2, varscan2
- IGHV4-59 | c.223A>G p.S75G | Missense Mutation (SNP) | VAF 102/293 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.022); catalogued as rs782652010; called by muse, varscan2
- IGLL1 | c.25G>T p.G9C | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV50770356; called by muse, mutect2, varscan2
- IGLV8-61 | c.138T>A p.C46* | Nonsense Mutation (SNP) | VAF 25/56 reads (45%) | catalogued as rs369521636; called by muse, mutect2, varscan2
- IGSF1 | c.361C>A p.L121I | Missense Mutation (SNP) | VAF 36/38 reads (95%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV63840345; called by muse, mutect2, varscan2
- IKZF1 | c.527A>T p.H176L | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV58791634; called by muse, mutect2, varscan2
- IL12RB1 | c.1769T>C p.I590T | Missense Mutation (SNP) | VAF 110/241 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.054); catalogued as COSV74045677; called by muse, mutect2, varscan2
- IL1B | c.48-2A>G p.X16_splice | Splice Site (SNP) | VAF 22/49 reads (45%) | catalogued as COSV54523209; called by muse, mutect2, varscan2
- IL21R | c.196A>T p.S66C | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV61972642; called by muse, mutect2, varscan2
- IL23R | c.587T>A p.V196D | Missense Mutation (SNP) | VAF 94/184 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61376328; called by muse, mutect2, varscan2
- IL4R | c.1820C>G p.S607* | Nonsense Mutation (SNP) | VAF 19/38 reads (50%) | catalogued as COSV50174136, COSV50186218; called by muse, mutect2, varscan2
- IMPG2 | c.1459C>T p.H487Y | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV51985733; called by muse, mutect2, varscan2
- INAVA | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.724); catalogued as COSV66257557; called by muse, mutect2
- INPP4A | c.2305A>G p.N769D (on ENST00000074304 / NM_001134224.1; = p.N730D on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV50832968; called by muse, mutect2, varscan2
- INSR | c.4123A>T p.T1375S | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV57173282; called by muse, mutect2, varscan2
- IPO11 | c.1852A>G p.M618V | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV57582556; called by muse, mutect2, varscan2
- IPO7 | c.1181A>T p.Q394L | Missense Mutation (SNP) | VAF 43/52 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63352899; called by muse, mutect2, varscan2
- IQCN | c.368T>C p.L123P | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101149069; called by muse, mutect2, varscan2
- IRX4 | c.952G>T p.E318* | Nonsense Mutation (SNP) | VAF 8/15 reads (53%) | catalogued as COSV51474963, COSV99180755; called by muse, varscan2
- ISM2 | c.1541G>A p.S514N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53637019; called by muse, mutect2, varscan2
- ITGA11 | c.1655T>A p.L552H | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV59882027; called by muse, varscan2
- ITGA4 | c.457T>G p.Y153D | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV52004286; called by muse, mutect2, varscan2
- ITGAD | c.1040A>T p.Q347L | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV66760219; called by muse, mutect2, varscan2
- ITGAD | c.1958T>C p.V653A | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as COSV66760223; called by muse, mutect2, varscan2
- ITGBL1 | c.886T>G p.C296G | Missense Mutation (SNP) | VAF 48/54 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66011973; called by muse, mutect2, varscan2
- ITIH4 | c.631-2A>T p.X211_splice | Splice Site (SNP) | VAF 16/47 reads (34%) | catalogued as COSV56578753; called by muse, mutect2, varscan2
- ITPR1 | c.1135G>T p.D379Y (on ENST00000354582; = p.D364Y on NM_002222.7) | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57004007; called by muse, mutect2, varscan2
- ITPR3 | c.6167T>A p.L2056Q | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65414901; called by muse, mutect2, varscan2
- IZUMO1R | c.436T>A p.W146R (on ENST00000440961; = p.W153R on NM_001199206.3) | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60623567; called by muse, mutect2, varscan2
- JAM2 | c.218T>A p.V73D | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57260684; called by muse, mutect2, varscan2
- KANK4 | c.2198C>T p.P733L | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV58094128; called by muse, mutect2, varscan2
- KATNAL2 | c.608A>T p.E203V (on ENST00000356157 / NM_001353899.1; = p.E131V on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); catalogued as COSV55308650; called by muse, mutect2, varscan2
- KATNIP | c.2691C>G p.H897Q | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV55174800, COSV55191920; called by muse, mutect2, varscan2
- KBTBD8 | c.1118A>T p.K373I | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV55131544; called by muse, mutect2, varscan2
- KCNA1 | c.667A>C p.I223L | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV66838700; called by muse, mutect2, varscan2
- KCNA3 | c.928C>A p.L310M | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63902603; called by muse, mutect2, varscan2
- KCNA5 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.335); catalogued as COSV52908792; called by muse, mutect2, varscan2
- KCNH7 | c.955T>A p.S319T | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV59813829; called by muse, mutect2, varscan2
- KCNK10 | c.389A>G p.H130R | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.48); PolyPhen benign (0.02); catalogued as rs1264947040, COSV56652570; called by muse, mutect2, varscan2
- KCNK13 | c.671A>T p.Y224F | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs1182914733, COSV56417796; called by muse, mutect2, varscan2
- KCNT1 | c.1070T>A p.L357Q (on ENST00000488444; = p.L376Q on NM_020822.3) | Missense Mutation (SNP) | VAF 41/56 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV53710868; called by muse, mutect2, varscan2
- KCNT1 | c.2538-2A>C p.X846_splice (on ENST00000488444; = p.X865_splice on NM_020822.3) | Splice Site (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99706790; called by mutect2, varscan2
- KCTD19 | c.2455T>C p.Y819H | Missense Mutation (SNP) | VAF 44/48 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58575253; called by muse, mutect2, varscan2
- KDM4C | c.2260-2A>T p.X754_splice | Splice Site (SNP) | VAF 27/29 reads (93%) | catalogued as COSV67193057; called by muse, mutect2
- KDR | c.1772T>G p.L591R | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.079); catalogued as COSV55776174; called by muse, mutect2, varscan2
- KDR | c.162G>A p.R54= | Splice Region (SNP) | VAF 57/111 reads (51%) | catalogued as COSV55757457; called by muse, mutect2, varscan2
- KIAA1109 | c.903A>T p.G301= | Splice Region (SNP) | VAF 54/106 reads (51%) | catalogued as COSV52692198; called by muse, mutect2, varscan2
- KIF16B | c.1144A>T p.R382* | Nonsense Mutation (SNP) | VAF 49/108 reads (45%) | catalogued as COSV61715214; called by muse, mutect2, varscan2
- KIF19 | c.2881T>C p.S961P | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.136); catalogued as COSV63430618; called by muse, mutect2, varscan2
- KIF21A | c.2449A>T p.R817* (on ENST00000361418 / NM_001378440.1; = p.R804* on NM_017641.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 38/114 reads (33%) | catalogued as COSV62778129; called by muse, mutect2, varscan2
- KIF5A | c.2225T>A p.L742Q | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as COSV54059175; called by muse, mutect2, varscan2
- KIF5C | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 91/192 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68927158; called by muse, mutect2, varscan2
- KLC2 | c.686A>G p.E229G | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV57584339; called by muse, mutect2, varscan2
- KLHL28 | c.580A>T p.T194S | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as COSV61889390; called by muse, mutect2, varscan2
- KLHL35 | c.893T>C p.L298P | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.964); catalogued as COSV66219701; called by muse, mutect2, varscan2
- KLHL38 | c.602T>C p.M201T | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.335); catalogued as COSV58089034; called by muse, mutect2, varscan2
- KMT2D | c.15706A>C p.N5236H | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV56486453; called by muse, mutect2, varscan2
- KNDC1 | c.2891C>G p.S964* | Nonsense Mutation (SNP) | VAF 22/28 reads (79%) | catalogued as COSV58846250; called by muse, mutect2, varscan2
- KPTN | c.290T>A p.V97E | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV54551973; called by muse, mutect2, varscan2
- KRBA1 | c.839C>A p.P280H | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757655966, COSV55444334; called by muse, mutect2, varscan2
- KRT1 | c.1512T>G p.S504= | Splice Region (SNP) | VAF 28/55 reads (51%) | catalogued as rs763592514, COSV52869310; called by muse, mutect2, varscan2
- KRT15 | c.738G>T p.E246D | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV54181978; called by muse, mutect2, varscan2
- KRT3 | c.7A>T p.R3* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV58817364; called by muse, mutect2, varscan2
- KRT32 | c.1051C>G p.L351V | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV56787424, COSV56788218; called by muse, mutect2, varscan2
- KRT35 | c.677A>G p.E226G | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV55844591; called by muse, mutect2, varscan2
- KRT40 | c.849G>A p.Q283= | Splice Region (SNP) | VAF 47/97 reads (48%) | catalogued as COSV66697070, COSV66697164; called by muse, mutect2, varscan2
- KRT40 | c.101T>A p.L34H | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.052); catalogued as COSV66697075; called by muse, mutect2, varscan2
- KRT6C | c.1588A>T p.S530C | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.319); catalogued as COSV52880573; called by muse, mutect2, varscan2
- KRT72 | c.1369G>T p.G457W | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as COSV53376866; called by muse, mutect2, varscan2
- KRT77 | c.1277A>G p.Q426R | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.474); catalogued as COSV59241510; called by muse, mutect2, varscan2
- KRT81 | c.640-2A>G p.X214_splice | Splice Site (SNP) | VAF 35/77 reads (45%) | catalogued as COSV59811404; called by muse, mutect2, varscan2
- KRT86 | c.728A>G p.Y243C | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs202150817, COSV53294331; called by muse, mutect2, varscan2
- KRTAP10-4 | c.730T>C p.S244P | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs782335154, COSV59980163; called by muse, mutect2, varscan2
- KRTAP11-1 | c.121T>G p.C41G | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.072); catalogued as COSV60093953, COSV60095491; called by muse, mutect2, varscan2
- KRTAP12-2 | c.329G>T p.C110F | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1555944774, COSV59980173; called by muse, mutect2, varscan2
- KRTAP4-5 | c.261G>T p.R87S | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100576843; called by muse, mutect2, varscan2
- KSR2 | c.217T>C p.C73R | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV60394884; called by muse, mutect2, varscan2
- LAMA2 | c.8336A>T p.D2779V | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70355115; called by muse, mutect2, varscan2
- LAMC1 | c.3793G>T p.V1265L | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51177631; called by muse, mutect2, varscan2
- LCA5 | c.581G>T p.S194I | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV63973105; called by muse, mutect2, varscan2
- LCK | c.926A>T p.Q309L | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as COSV60742753; called by muse, mutect2, varscan2
- LDLRAD2 | c.291C>A p.N97K | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV60829685; called by muse, mutect2, varscan2
- LDLRAD3 | c.152G>T p.G51V | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1565176450, COSV59688742; called by muse, mutect2, varscan2
- LGR6 | c.2477T>A p.L826Q (on ENST00000367278 / NM_001017403.1; = p.L774Q on NM_021636.3) | Missense Mutation (SNP) | VAF 15/16 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55166299; called by muse, mutect2, varscan2
- LHCGR | c.784A>T p.R262* | Nonsense Mutation (SNP) | VAF 20/53 reads (38%) | catalogued as COSV54303155; called by muse, mutect2, varscan2
- LHX2 | c.1219T>C p.*407Qext*1 | Nonstop Mutation (SNP) | VAF 54/68 reads (79%) | catalogued as COSV65319128; called by muse, mutect2, varscan2
- LILRB5 | c.1476C>T p.A492= (on ENST00000449561 / NM_001081442.3; = p.A491= on NM_006840.5) | Splice Region (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100300843, COSV60257864; called by mutect2, varscan2
- LIM2 | c.258C>A p.F86L (on ENST00000596399 / NM_001161748.2; = p.F128L on NM_030657.4) | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as COSV55742362, COSV99702170; called by muse, mutect2, varscan2
- LIN28A | c.259T>A p.L87M | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54263252; called by muse, varscan2
- LMAN1L | c.625A>T p.S209C | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV59003746; called by muse, mutect2, varscan2
- LRCH1 | c.1772A>G p.E591G | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60853464; called by muse, mutect2, varscan2
- LRIT1 | c.1642T>A p.C548S | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV64513565; called by muse, mutect2, varscan2
- LRP1B | c.5581T>A p.C1861S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67275062; called by muse, mutect2, varscan2
- LRP2 | c.6712G>A p.G2238S | Missense Mutation (SNP) | VAF 62/142 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as rs764132183, COSV55574480; called by muse, mutect2, varscan2
- LRRC10 | c.514A>G p.I172V | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.114); catalogued as rs1256806283, COSV64060724; called by muse, mutect2, varscan2
- LRRC36 | c.71-2A>C p.X24_splice | Splice Site (SNP) | VAF 29/33 reads (88%) | catalogued as COSV61719406; called by muse, mutect2, varscan2
- LRRC4 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50818559; called by muse, mutect2, varscan2
- LRRC57 | c.356A>T p.Q119L | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV53001204; called by muse, mutect2, varscan2
- LRRC7 | c.2252C>T p.A751V (on ENST00000651989 / NM_001370785.2; = p.A718V on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.031); catalogued as COSV50414558, COSV50485589; called by muse, mutect2, varscan2
- LRRIQ4 | c.212A>G p.K71R | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61620246; called by muse, mutect2, varscan2
- LRRK1 | c.4573T>A p.F1525I | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52626054; called by muse, mutect2, varscan2
- LRRK1 | c.5191A>G p.M1731V | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs921178428, COSV52626067; called by muse, mutect2, varscan2
- LTBP2 | c.1202A>T p.Q401L | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56214170; called by muse, mutect2, varscan2
- LUM | c.167T>A p.L56Q | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.763); catalogued as COSV57128936, COSV57129236; called by muse, mutect2, varscan2
- LY9 | c.613T>C p.S205P | Missense Mutation (SNP) | VAF 133/383 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.177); catalogued as COSV54438037; called by muse, mutect2, varscan2
- LYPD3 | c.29A>T p.Q10L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV54989656; called by muse, mutect2
- LYPD4 | c.418T>G p.C140G | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV58028475; called by muse, mutect2, varscan2
- MACC1 | c.2248T>A p.W750R | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60546447; called by muse, mutect2, varscan2
- MAP1B | c.5272G>C p.D1758H | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as COSV57106464; called by muse, mutect2, varscan2
- MAP2K2 | c.230A>G p.E77G | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53569719; called by muse, mutect2, varscan2
- MAP3K4 | c.3776-2A>T p.X1259_splice | Splice Site (SNP) | VAF 135/282 reads (48%) | catalogued as COSV62338515; called by muse, mutect2, varscan2
- MAPK7 | c.2441A>T p.Q814L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as COSV55191887; called by muse, mutect2, varscan2
- MARCHF4 | c.1004G>T p.R335L | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.343); catalogued as COSV56105119, COSV56108597; called by muse, mutect2, varscan2
- MBOAT1 | c.742A>T p.T248S | Missense Mutation (SNP) | VAF 69/173 reads (40%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.469); catalogued as COSV61127850; called by muse, mutect2, varscan2
- MCAM | c.137T>G p.L46R | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50685254; called by muse, mutect2, varscan2
- MCFD2 | c.302A>G p.H101R | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs746904307, COSV60178461; called by muse, mutect2, varscan2
- MCM10 | c.684A>T p.R228S (on ENST00000484800 / NM_182751.3; = p.R227S on NM_018518.5) | Missense Mutation (SNP) | VAF 61/127 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.036); catalogued as COSV66336842; called by muse, mutect2, varscan2
- MCM3 | c.2457A>T p.*819Cext*38 (on ENST00000229854 / NM_001366374.2; = p.*809Cext*38 on NM_002388.6 and 5 other RefSeq transcripts) | Nonstop Mutation (SNP) | VAF 28/55 reads (51%) | catalogued as COSV57719437; called by muse, mutect2, varscan2
- MCM3AP | c.2692A>T p.I898F | Missense Mutation (SNP) | VAF 31/39 reads (79%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV52445602; called by muse, mutect2, varscan2
- MCTP2 | c.1537G>A p.V513M | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59150405; called by muse, mutect2, varscan2
- MCUR1 | c.1030A>G p.I344V | Missense Mutation (SNP) | VAF 83/199 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs1244377375, COSV64847285; called by muse, mutect2, varscan2
- MDC1 | c.5274G>T p.W1758C | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.339); catalogued as COSV64527654; called by muse, mutect2, varscan2
- MDN1 | c.14692A>G p.T4898A | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.039); catalogued as rs1276952037, COSV65530275; called by muse, varscan2
- MDN1 | c.14563G>T p.E4855* | Nonsense Mutation (SNP) | VAF 28/62 reads (45%) | catalogued as COSV65530281; called by muse, mutect2, varscan2
- METTL21C | c.252A>G p.I84M | Missense Mutation (SNP) | VAF 105/115 reads (91%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.925); catalogued as COSV57433620; called by muse, mutect2, varscan2
- METTL27 | c.365A>T p.Q122L | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.818); catalogued as COSV52897211; called by muse, mutect2, varscan2
- MEX3B | c.380T>C p.I127T | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV61664363; called by muse, mutect2, varscan2
- MFSD6L | c.1709G>A p.G570E | Missense Mutation (SNP) | VAF 26/27 reads (96%) | SIFT tolerated (1); PolyPhen benign (0.056); catalogued as rs1162800095, COSV61688920; called by muse, mutect2, varscan2
- MGAT4C | c.935T>A p.M312K | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV100152766, COSV59837891; called by muse, mutect2, varscan2
- MIB1 | c.287T>A p.I96N | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV55094995; called by muse, mutect2, varscan2
- MICU2 | c.450A>T p.R150S | Missense Mutation (SNP) | VAF 77/168 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66675497; called by muse, mutect2, varscan2
- MIIP | c.302A>T p.Q101L | Missense Mutation (SNP) | VAF 51/84 reads (61%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV52428819; called by muse, mutect2, varscan2
- MILR1 | c.956A>T p.Q319L | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV74151755; called by muse, mutect2, varscan2
- MINAR1 | c.1253A>G p.K418R | Missense Mutation (SNP) | VAF 85/181 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as COSV59586615; called by muse, mutect2, varscan2
- MISP | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.381); catalogued as COSV53120975; called by muse, mutect2, varscan2
- MISP | c.1056G>T p.Q352H | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV53122359; called by muse, mutect2, varscan2
- MISP | c.1588G>T p.V530L | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.281); catalogued as COSV53122372; called by muse, varscan2
- MISP | c.1655A>T p.E552V | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV53122378; called by muse, varscan2
- MLLT3 | c.958T>A p.C320S | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT tolerated (0.82); PolyPhen benign (0.01); catalogued as COSV63502671; called by muse, mutect2, varscan2
- MMP10 | c.1227-2A>T p.X409_splice | Splice Site (SNP) | VAF 16/48 reads (33%) | catalogued as COSV54247843; called by muse, mutect2, varscan2
- MMP14 | c.752G>T p.S251I | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV61289549; called by muse, mutect2, varscan2
- MMP7 | c.707A>T p.Y236F | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52773221; called by muse, mutect2, varscan2
- MOG | c.239A>T p.Y80F | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65321788; called by muse, mutect2, varscan2
- MORC2 | c.1414T>C p.S472P (on ENST00000397641 / NM_001303256.3; = p.S410P on NM_014941.3) | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53202696; called by muse, mutect2, varscan2
- MOS | c.174G>T p.E58D | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as rs1172732244, COSV61336990; called by muse, mutect2, varscan2
- MOV10L1 | c.3499A>G p.T1167A | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV53179326; called by muse, mutect2, varscan2
- MPHOSPH8 | c.687A>T p.K229N | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.976); catalogued as COSV64057703; called by muse, mutect2, varscan2
- MPO | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 68/150 reads (45%) | catalogued as COSV56569022; called by muse, mutect2, varscan2
- MRC2 | c.967G>T p.E323* | Nonsense Mutation (SNP) | VAF 35/72 reads (49%) | catalogued as COSV57644614; called by muse, mutect2, varscan2
- MRGPRE | c.612G>T p.E204D | Missense Mutation (SNP) | VAF 14/15 reads (93%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.721); catalogued as COSV67745988; called by muse, mutect2, varscan2
- MROH7 | c.1081A>T p.K361* | Nonsense Mutation (SNP) | VAF 51/90 reads (57%) | catalogued as COSV59877903; called by muse, mutect2, varscan2
- MROH7 | c.3669G>A p.G1223= | Splice Region (SNP) | VAF 26/42 reads (62%) | catalogued as COSV64888323; called by muse, mutect2, varscan2
- MRPL30 | c.395A>G p.E132G | Missense Mutation (SNP) | VAF 54/116 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.094); catalogued as COSV57667698; called by muse, mutect2, varscan2
- MST1R | c.4028A>T p.Q1343L | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV56573912; called by muse, mutect2, varscan2
- MTF1 | c.1451A>G p.E484G | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.214); catalogued as COSV65990699; called by muse, mutect2, varscan2
- MTHFD1 | c.689G>T p.G230V | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53703863; called by muse, mutect2, varscan2
- MTIF2 | c.791G>T p.G264V | Missense Mutation (SNP) | VAF 83/166 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55054246; called by muse, mutect2, varscan2
- MTMR8 | c.1588G>C p.D530H | Missense Mutation (SNP) | VAF 82/87 reads (94%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV100878165, COSV66393759, COSV66396307; called by muse, mutect2, varscan2
- MTRR | c.598G>T p.A200S (on ENST00000264668; = p.A173S on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as COSV52944560, COSV52946838; called by muse, mutect2, varscan2
- MUC16 | c.25183A>G p.I8395V | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV67479551; called by muse, mutect2, varscan2
- MUC16 | c.19939A>G p.I6647V | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); catalogued as COSV67494526; called by muse, mutect2, varscan2
- MUC16 | c.16186A>T p.S5396C | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV67494532; called by muse, mutect2, varscan2
- MUC16 | c.10404C>A p.D3468E | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.351); catalogued as COSV67494538; called by muse, mutect2, varscan2
- MUC17 | c.264C>A p.N88K | Missense Mutation (SNP) | VAF 58/107 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.19); catalogued as COSV60303420; called by muse, mutect2, varscan2
- MUC17 | c.11150C>A p.P3717H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV60303429; called by muse, mutect2, varscan2
- MUC2 | c.2349C>A p.S783R | Missense Mutation (SNP) | VAF 19/21 reads (90%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as rs770734186; called by muse, mutect2, varscan2
- MUC5AC | c.1849T>A p.C617S | Missense Mutation (SNP) | VAF 43/50 reads (86%) | SIFT deleterious (0); catalogued as COSV100650708; called by muse, mutect2, varscan2
- MYBPC3 | c.335A>T p.E112V | Missense Mutation (SNP) | VAF 75/178 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV57033750; called by muse, mutect2, varscan2
- MYCBP2 | c.917G>A p.G306D (on ENST00000357337; = p.G344D on NM_015057.5) | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62039122; called by muse, mutect2, varscan2
- MYCBPAP | c.800T>A p.L267Q | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as COSV60412360; called by muse, mutect2, varscan2
- MYH1 | c.805+2T>A p.X269_splice | Splice Site (SNP) | VAF 37/42 reads (88%) | catalogued as COSV56857124; called by muse, mutect2, varscan2
- MYH15 | c.3454A>C p.T1152P | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as COSV56319702; called by muse, mutect2, varscan2
- MYH15 | c.3320A>G p.E1107G | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56319713; called by muse, mutect2, varscan2
- MYH2 | c.3068T>C p.V1023A | Missense Mutation (SNP) | VAF 40/49 reads (82%) | SIFT deleterious (0.05); PolyPhen benign (0.234); catalogued as COSV55448463; called by muse, mutect2, varscan2
- MYH6 | c.3811T>A p.S1271T | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV62454523; called by muse, mutect2, varscan2
- MYH7 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as CM1410887, COSV62520552, COSV62523895; called by muse, varscan2
- MYH9 | c.4777G>T p.E1593* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as COSV53393206; called by muse, mutect2, varscan2
- MYMK | c.270A>T p.E90D | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.965); catalogued as COSV60601613; called by muse, mutect2, varscan2
- MYO18B | c.7108A>T p.T2370S | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV59127117; called by muse, mutect2, varscan2
- MYO1G | c.2897A>T p.Q966L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV51857082; called by muse, mutect2, varscan2
- MYO3A | c.3916A>G p.K1306E | Missense Mutation (SNP) | VAF 82/170 reads (48%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as COSV56349669; called by muse, mutect2, varscan2
- MYO3B | c.1483T>C p.Y495H | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58717831; called by muse, mutect2, varscan2
- MYO3B | c.2426T>A p.L809Q | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58717841; called by muse, mutect2, varscan2
- MYO6 | c.1771-2A>T p.X591_splice | Splice Site (SNP) | VAF 34/61 reads (56%) | catalogued as COSV64121413; called by muse, mutect2, varscan2
- MYO7A | c.3991A>T p.K1331* | Nonsense Mutation (SNP) | VAF 54/103 reads (52%) | catalogued as COSV68686837, COSV68687066; called by muse, mutect2, varscan2
- MYOC | c.933C>G p.Y311* | Nonsense Mutation (SNP) | VAF 22/130 reads (17%) | catalogued as COSV50679018; called by muse, mutect2, varscan2
- NAALAD2 | c.1461G>T p.W487C | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58966174; called by muse, mutect2, varscan2
- NABP2 | c.320A>T p.N107I | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV57193692; called by muse, mutect2, varscan2
- NAPSA | c.1169T>G p.M390R | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs768316343, COSV53799156; called by muse, mutect2, varscan2
- NBAS | c.380-2A>T p.X127_splice | Splice Site (SNP) | VAF 38/102 reads (37%) | catalogued as COSV55735447, COSV55737777; called by muse, mutect2, varscan2
- NBR1 | c.486A>T p.R162S | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV57835613; called by muse, mutect2, varscan2
- NBR1 | c.2437G>C p.E813Q | Missense Mutation (SNP) | VAF 71/162 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.732); catalogued as COSV57832934; called by muse, mutect2, varscan2
- NCAM2 | c.1252A>G p.I418V | Missense Mutation (SNP) | VAF 134/300 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV53103668; called by muse, mutect2, varscan2
- NCAPG | c.288A>C p.L96F | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV52272750; called by muse, varscan2
- NCOR2 | c.1595A>T p.E532V | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62304511; called by muse, mutect2, varscan2
- NDST2 | c.706A>G p.T236A | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.883); catalogued as COSV55217931; called by muse, mutect2, varscan2
- NDST4 | c.454A>G p.K152E | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.491); catalogued as COSV52137657; called by muse, mutect2, varscan2
- NDUFAF4 | c.460A>T p.K154* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as COSV60214621; called by muse, mutect2, varscan2
- NECAB3 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs200489455, COSV55777483; called by muse, mutect2, varscan2
- NEK5 | c.777A>C p.L259F | Missense Mutation (SNP) | VAF 100/225 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62881989; called by muse, mutect2, varscan2
- NELL2 | c.1091A>T p.Q364L | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV61585658; called by muse, mutect2, varscan2
- NEUROD1 | c.470T>C p.L157P | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54551173; called by muse, mutect2, varscan2
- NEUROD4 | c.928G>T p.D310Y | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV54471402, COSV54474137; called by muse, mutect2, varscan2
- NFATC4 | c.1277G>T p.R426I | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51611400; called by muse, mutect2, varscan2
- NFIX | c.257A>T p.E86V | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62181090; called by muse, mutect2, varscan2
- NHLH2 | c.356T>A p.L119Q | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57202949; called by muse, mutect2, varscan2
- NHLRC4 | c.119T>C p.L40P | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50321764; called by muse, mutect2, varscan2
- NID2 | c.3101C>G p.P1034R | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53502919; called by muse, mutect2, varscan2
- NKX2-2 | c.789C>A p.H263Q | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.979); catalogued as COSV65820367; called by muse, mutect2, varscan2
- NKX2-8 | c.107A>T p.Q36L | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV51874688; called by muse, mutect2, varscan2
- NLE1 | c.1197G>T p.W399C | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50104651; called by muse, mutect2, varscan2
- NLGN4X | c.2344A>T p.I782F | Missense Mutation (SNP) | VAF 54/63 reads (86%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV52036513; called by muse, mutect2, varscan2
- NLK | c.1049T>A p.L350* | Nonsense Mutation (SNP) | VAF 24/58 reads (41%) | catalogued as COSV63490759; called by muse, mutect2, varscan2
- NLRP2 | c.2239C>A p.L747I | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as rs753727675, COSV54760435, COSV54760509; called by muse, mutect2, varscan2
- NLRP2 | c.2797G>T p.G933W | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54760442; called by muse, varscan2
- NLRP2 | c.2860T>C p.C954R | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54760450; called by muse, varscan2
- NLRP8 | c.1973T>A p.V658E | Missense Mutation (SNP) | VAF 31/33 reads (94%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV52593952; called by muse, mutect2, varscan2
- NOS1 | c.2966T>C p.L989P | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57621952; called by muse, mutect2, varscan2
- NOS1 | c.1947C>A p.D649E | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.68); PolyPhen benign (0.177); catalogued as COSV57621962; called by muse, mutect2, varscan2
- NOTCH3 | c.1193-2A>T p.X398_splice | Splice Site (SNP) | VAF 22/57 reads (39%) | catalogued as COSV54650363; called by muse, mutect2, varscan2
- NOX3 | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.548); catalogued as COSV50163507; called by muse, mutect2, varscan2
- NOX4 | c.1540G>C p.A514P | Missense Mutation (SNP) | VAF 93/220 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV54464873; called by muse, mutect2, varscan2
- NPAP1 | c.2858C>A p.T953N | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV61508700, COSV61511312; called by muse, mutect2, varscan2
- NPAS2 | c.1139A>T p.K380M | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59562224; called by muse, mutect2, varscan2
- NPAS2 | c.1396C>G p.P466A | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV59562238; called by muse, mutect2, varscan2
- NPFFR2 | c.370A>T p.T124S | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.057); catalogued as COSV58154486; called by muse, mutect2, varscan2
- NPHP4 | c.1561A>T p.R521W | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV65398055; called by muse, mutect2, varscan2
- NPNT | c.1493A>G p.Q498R | Missense Mutation (SNP) | VAF 62/122 reads (51%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.968); catalogued as COSV59757030; called by muse, mutect2, varscan2
- NR4A3 | c.383T>A p.L128Q | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0.03); PolyPhen benign (0.221); catalogued as COSV58248377; called by muse, mutect2, varscan2
- NSD1 | c.2554A>G p.I852V | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.952); catalogued as COSV61784717; called by muse, mutect2, varscan2
- NTRK2 | c.475A>T p.I159F | Missense Mutation (SNP) | VAF 148/162 reads (91%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV52882509; called by muse, mutect2, varscan2
- NXPE4 | c.751T>A p.C251S | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs184063316, COSV64944416; called by muse, mutect2, varscan2
- ODAPH | c.315T>G p.Y105* | Nonsense Mutation (SNP) | VAF 71/191 reads (37%) | catalogued as COSV61141864; called by muse, mutect2, varscan2
- OPA1 | c.650G>C p.G217A (on ENST00000361510 / NM_130837.3; = p.G199A on NM_015560.3) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV62483406; called by muse, mutect2, varscan2
- OR10G8 | c.415T>A p.S139T | Missense Mutation (SNP) | VAF 134/229 reads (59%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs1380154007, COSV70909435; called by muse, mutect2, varscan2
- OR10Z1 | c.415A>T p.T139S | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV63526544; called by muse, varscan2
- OR10Z1 | c.428A>T p.Q143L | Missense Mutation (SNP) | VAF 129/165 reads (78%) | SIFT tolerated (0.19); PolyPhen benign (0.066); catalogued as COSV63526549; called by muse, varscan2
- OR11G2 | c.997A>T p.K333* | Nonsense Mutation (SNP) | VAF 25/73 reads (34%) | catalogued as COSV62133135; called by muse, mutect2, varscan2
- OR12D3 | c.65A>T p.Q22L | Missense Mutation (SNP) | VAF 71/196 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV65830361; called by muse, varscan2
- OR1A2 | c.77T>A p.V26D | Missense Mutation (SNP) | VAF 34/47 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as COSV67936816; called by muse, mutect2, varscan2
- OR1D2 | c.188T>A p.L63Q | Missense Mutation (SNP) | VAF 87/105 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV58922466; called by muse, mutect2, varscan2
- OR1D5 | c.299A>G p.Q100R | Missense Mutation (SNP) | VAF 72/100 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73859668; called by muse, mutect2, varscan2
- OR2AT4 | c.593C>T p.T198I | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.228); catalogued as COSV59407126, COSV59407709; called by muse, mutect2, varscan2
- OR2H2 | c.415T>G p.C139G | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100590160, COSV63544546; called by muse, mutect2, varscan2
- OR2J3 | c.362T>A p.M121K | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV65849706; called by muse, mutect2, varscan2
- OR2S2 | c.577A>G p.I193V | Missense Mutation (SNP) | VAF 42/73 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.364); catalogued as COSV59531301; called by muse, mutect2, varscan2
- OR4A15 | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV59037737, COSV59038238; called by muse, mutect2, varscan2
- OR4A15 | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as COSV59033747; called by muse, mutect2, varscan2
- OR4D5 | c.862A>T p.T288S | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.486); catalogued as COSV58309543; called by muse, mutect2, varscan2
- OR4K2 | c.461T>C p.M154T | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs776860961, COSV53851661; called by muse, mutect2, varscan2
- OR51A2 | c.894A>C p.K298N | Missense Mutation (SNP) | VAF 135/152 reads (89%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV66748787; called by muse, mutect2, varscan2
- OR51A7 | c.37C>A p.L13I | Missense Mutation (SNP) | VAF 21/27 reads (78%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV63788971; called by muse, mutect2, varscan2
- OR51F2 | c.319C>A p.H107N | Missense Mutation (SNP) | VAF 45/53 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59066098; called by muse, mutect2, varscan2
- OR51G2 | c.86A>C p.H29P | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV58995103; called by muse, mutect2, varscan2
- OR51S1 | c.103T>A p.W35R | Missense Mutation (SNP) | VAF 52/61 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV59060236; called by muse, mutect2, varscan2
- OR52N5 | c.706A>T p.S236C | Missense Mutation (SNP) | VAF 47/60 reads (78%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV57699501; called by muse, mutect2, varscan2
- OR5AP2 | c.92G>T p.G31V | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57257697, COSV57259050; called by muse, mutect2, varscan2
- OR5B3 | c.779C>A p.P260H | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV58678663; called by muse, mutect2, varscan2
- OR6A2 | c.625A>G p.I209V | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.455); catalogued as COSV60265890; called by muse, mutect2, varscan2
- OR6C3 | c.664A>G p.I222V | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.074); catalogued as COSV65572121; called by muse, mutect2, varscan2
- OR6K2 | c.811T>A p.W271R | Missense Mutation (SNP) | VAF 153/383 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.972); catalogued as COSV62744229; called by muse, varscan2
- OR7G1 | c.428T>A p.L143* | Nonsense Mutation (SNP) | VAF 31/87 reads (36%) | catalogued as COSV53319001; called by muse, mutect2, varscan2
- OR8B8 | c.579T>A p.Y193* | Nonsense Mutation (SNP) | VAF 70/153 reads (46%) | catalogued as COSV60145779; called by muse, mutect2, varscan2
- OR8I2 | c.683A>T p.Q228L | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as COSV56170492; called by muse, mutect2, varscan2
- OR8J3 | c.192A>T p.R64S | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.283); catalogued as COSV56884318; called by muse, mutect2, varscan2
- OR8K1 | c.770T>C p.F257S | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV54404398; called by muse, mutect2, varscan2
- OR8K1 | c.910A>T p.K304* | Nonsense Mutation (SNP) | VAF 16/41 reads (39%) | catalogued as COSV54404652; called by muse, mutect2, varscan2
- OR8K3 | c.577C>A p.H193N | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.02); catalogued as COSV57133162; called by muse, mutect2, varscan2
- OR9G1 | c.730C>A p.L244M | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV56454238; called by muse, varscan2
- ORAI3 | c.754A>G p.M252V | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.977); catalogued as COSV52692533; called by muse, mutect2, varscan2
- OTOF | c.2842C>T p.P948S (on ENST00000272371 / NM_194248.3; = p.P201S on NM_004802.4) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55519861; called by muse, mutect2, varscan2
- OTOP1 | c.1242T>A p.C414* | Nonsense Mutation (SNP) | VAF 28/52 reads (54%) | catalogued as COSV56396811; called by muse, mutect2, varscan2
- OXSM | c.598G>T p.G200C | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55002659; called by muse, mutect2, varscan2
- P2RY1 | c.751A>T p.N251Y | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.347); catalogued as COSV59310460; called by muse, mutect2, varscan2
- P3H2 | c.1453-2A>T p.X485_splice | Splice Site (SNP) | VAF 40/89 reads (45%) | catalogued as COSV60027853; called by muse, mutect2, varscan2
- PADI1 | c.1004A>T p.K335M | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64939308; called by muse, mutect2, varscan2
- PAK3 | c.404T>C p.L135P (on ENST00000262836 / NM_001324328.2; = p.L120P on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 213/237 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53280670; called by muse, mutect2, varscan2
- PAK5 | c.1662A>T p.R554S | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV62037972; called by muse, mutect2, varscan2
- PAK5 | c.1211T>A p.L404H | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.41); catalogued as COSV62037977; called by muse, mutect2, varscan2
- PAK5 | c.304A>G p.K102E | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.375); catalogued as COSV62037983; called by muse, mutect2, varscan2
- PARD3B | c.1199G>T p.R400I | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62530784; called by muse, mutect2, varscan2
- PATJ | c.3857A>T p.E1286V | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56254319; called by muse, mutect2, varscan2
- PAX4 | c.776C>A p.S259Y | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.575); catalogued as rs529976183, COSV58389006, COSV58391705; called by muse, mutect2, varscan2
879 further variants in this file (463 protein-altering or splice-affecting, 384 silent, 32 other) are not listed here.
